Gene-level copy-number profile of tumor specimen RC-B5D4-TBP1-A from RC case RC-B5D4, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Prolymphocytic leukemia, T-cell type; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.6 years (21,387 days).
Specimen RC-B5D4-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6830373d-60ff-43d7-9b80-2144658ee5c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B5D4-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/2ed844e9-812f-4bcf-ab9a-89baf61d1359

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 136; copy number 1: 8,154; copy number 2: 46,900; copy number 3: 3,204.

Homozygous deletions (total copy number 0; autosomes only): 136 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,300,322, 8 genes (within-gene range 0–1): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr7:142,670,740–142,802,748, 24 genes: TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr11:90,017,611–90,087,131, 8 genes: AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1.
- chr14:22,086,407–22,552,156, 96 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,154. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
